Somatic mutation profile of tumor specimen TARGET-20-PATJXZ-03A (aliquot TARGET-20-PATJXZ-03A-01D) from TARGET case TARGET-20-PATJXZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.1 years (5,531 days).
Specimen TARGET-20-PATJXZ-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6379ed7-a9bc-4e77-8c4c-1ad98aa45471.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATJXZ-14A (Bone Marrow Normal), aliquot TARGET-20-PATJXZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54079a07-9c20-4ef1-b725-01b13df2d114

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 33/107 reads (31%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLT3 | c.1471G>C p.V491L | Missense Mutation (SNP) | VAF 227/568 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by muse, mutect2, varscan2
- TET2 | c.4136C>T p.A1379V | Missense Mutation (SNP) | VAF 124/285 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54422965; called by muse, mutect2, varscan2
- NRXN1 | c.*2854T>A | 3'UTR (SNP) | VAF 212/534 reads (40%) | called by muse, mutect2, varscan2
